Gene-level copy-number profile of tumor specimen MP2PRT-PATIAN-TMP1-A from MP2PRT case MP2PRT-PATIAN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.7 years (1,700 days).
Specimen MP2PRT-PATIAN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file abb946ae-5e24-405c-b23e-9492ae0cefd2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATIAN-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/66669ac3-e04b-4601-8e1b-63065e1f0288

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 712; copy number 2: 38,654; copy number 3: 1,643; copy number 4: 13,560; copy number 5: 689; copy number 6: 3,067.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–1): TRDD1, TRDD2.
- chr14:105,851,705–106,122,709, 61 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–2): IGHVIII-16-1.
- chr16:11,926,199–11,926,307, 1 gene: AC007216.5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,412 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:196,739,857–196,832,647, 1 gene, copy number 5 (within-gene range 2–5): PAK2.
- chr3:196,784,980–196,785,086, 1 gene, copy number 5: RNU6-42P.
- chr4:49,096–2,732,573, 93 genes, copy number 5 (broad region; genes not listed).
- chr4:37,821,361–40,811,184, 73 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:58,198–58,915, 1 gene, copy number 6: AC113430.1.
- chr6:158,515,605–158,926,571, 15 genes, copy number 5: CACYBPP3, TMEM181, TATDN2P2, MIR7161, DYNLT1, SYTL3, AMZ2P2, MIR3918, EZR, EZR-AS1, OSTCP1, AL627422.2, C6orf99, AL627422.1, RNU6-293P.
- chr7:38,269,491–38,311,808, 7 genes, copy number 5 (within-gene range 2–5): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr21:13,038,160–46,691,226, 722 genes, copy number 6 (broad region; genes not listed).
- chr22:35,257,452–50,801,309, 499 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 712. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
